Somatic mutation profile of tumor specimen MP2PRT-PAVYKW-TBP1-A (aliquot MP2PRT-PAVYKW-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVYKW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 9.3 years (3,415 days).
Specimen MP2PRT-PAVYKW-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b933d37a-56ac-466b-b2ae-817a32fac16e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYKW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYKW-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9e611c5-252d-4d9f-91c5-347b9fa2ba51

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 113/318 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 99/382 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CELSR3 | c.3319G>A p.V1107M | Missense Mutation (SNP) | VAF 162/397 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780764728; called by muse, mutect2, varscan2
- EXO1 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 84/187 reads (45%) | catalogued as rs761495515, COSV62220002; called by muse, mutect2, varscan2
- GPR161 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 120/299 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as rs758001918, COSV54787684; called by muse, mutect2, varscan2
- IQGAP3 | c.4363G>A p.A1455T | Missense Mutation (SNP) | VAF 138/350 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as rs368191209; called by muse, mutect2
- NAA11 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 154/544 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs761201577, COSV54515009; called by muse, mutect2, varscan2
- NUFIP2 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 106/427 reads (25%) | catalogued as COSV56606401; called by muse, mutect2, varscan2
- PI15 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 148/387 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs772197197, COSV52639690; called by muse, mutect2, varscan2
- SCAF11 | c.2929T>C p.C977R | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1489609271; called by muse, mutect2, varscan2
- FAM83B | c.1179G>T p.Q393H | Missense Mutation (SNP) | VAF 109/424 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- FAT4 | c.6707G>T p.S2236I | Missense Mutation (SNP) | VAF 122/456 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRO | c.328A>G p.S110G | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.279); called by muse, mutect2
- ROBO1 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 11/319 reads (3%) | called by muse, mutect2
- SOX5 | c.1469A>G p.N490S | Missense Mutation (SNP) | VAF 120/258 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3399G>A p.S1133= | Silent (SNP) | VAF 153/434 reads (35%) | catalogued as rs540993813, COSV101001943; called by muse, mutect2, varscan2
- AQP8 | c.660G>A p.V220= | Silent (SNP) | VAF 127/344 reads (37%) | called by muse, mutect2, varscan2
- CROCC2 | c.2379C>T p.S793= | Silent (SNP) | VAF 13/373 reads (3%) | called by muse, mutect2
- KRTAP12-4 | c.48C>A p.G16= | Silent (SNP) | VAF 47/888 reads (5%) | called by muse, mutect2
- MDGA1 | c.942G>C p.V314= | Silent (SNP) | VAF 23/574 reads (4%) | called by muse, mutect2
- MUC4 | c.8733G>A p.T2911= | Silent (SNP) | VAF 172/852 reads (20%) | catalogued as rs28385894; called by muse, varscan2
- SLC9A3 | c.*233_*234insTGCGCCGGGGGCGGGGCC | 3'UTR (INS) | VAF 7/78 reads (9%) | called by pindel, varscan2*
